Gene-level copy-number profile of tumor specimen C3N-03052-01 (profiled together with C3N-03052-02) from CPTAC case C3N-03052, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 63.0 years (23,009 days).
Specimen C3N-03052-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 20405057-ff93-4959-8f7e-ade4646d6887.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03052-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/663ac54e-15b8-4308-b0c4-65582aa1e3fc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 314; copy number 2: 10,645; copy number 3: 15,832; copy number 4: 20,231; copy number 5: 5,629; copy number 6: 4,316; copy number 7: 1,368; copy number 8: 19; copy number 9: 201; copy number 10: 127; copy number 11: 49; copy number 14: 162; copy number 16: 11.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,620,506–105,673,314, 7 genes (within-gene range 0–5): IGHG4, MIR8071-1, IGHG2, MIR8071-2, COPDA1, IGHGP, ELK2AP.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 550 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–146,461,859, 108 genes, copy number 10 (broad region; genes not listed).
- chr1:196,774,813–196,795,407, 1 gene, copy number 11: CFHR3.
- chr5:58,198–693,352, 27 genes, copy number 9: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1.
- chr5:850,291–10,440,388, 180 genes, copy number 9–16 (within-gene range 6–16) (broad region; genes not listed).
- chr5:29,848,684–44,066,731, 234 genes, copy number 9–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 313. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
